Surgical pathology report (de-identified scan), TCGA case TCGA-ZB-A96E, project TCGA-THYM (Thymoma), tissue source site Thoraxklinik, specimen TCGA-ZB-A96E-01A (Primary Tumor).

Name:

Identifier:

Unique Patient #:

Tumor Type : Thymoma

Pathology Report-Summary:

Material:

tumor: 8.0 x 8.0 x 3.0 cm

focal invasion through capsule

Diagnosis:

Type A-Thymoma (with focal TypeA/B)

pT2, pN0 (0/7)

Masaoka: II.1

Immunohistochemistry

epithelial cells positive for: CK5/6
strong membrane staining for EGFR

epithelial cells negative for: c-kit, CD5

CD1a, CD99-positive immature T-lymphocytes, partially also positive for CD5
sparsely CD20-positive lymphocytes

C6UF ICD-O-3
Thymoma, type A, malignant 8581/3
path Thymoma, type A (w/focal type
AB)malignant 8582/3
Site Thymus C37.9
Q2412/14

Source: NCI Genomic Data Commons file 0c0dfa9a-9cad-4f39-a679-395b2cad0c10 (TCGA-ZB-A96E.3CB6F5C3-25B8-41F3-8E21-32F865CF0FF0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).